Somatic mutation profile of tumor specimen TCGA-22-4607-01A (aliquot TCGA-22-4607-01A-01D-1267-08) from TCGA case TCGA-22-4607, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 75.6 years (27,601 days).
Specimen TCGA-22-4607-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) af347c5e-42ff-40b5-a2dd-393ac65f7cef.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-22-4607-11A (Solid Tissue Normal), aliquot TCGA-22-4607-11A-01D-1267-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5f9fadff-8b26-40f8-a692-003647b33786

The open-access MAF lists 58 somatic variants for this specimen: 49 protein-altering or splice-affecting, 8 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 40, Silent 8, Nonsense Mutation 4, Splice Site 3, Frame Shift Ins 1, In Frame Del 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.527G>T p.C176F | Missense Mutation (SNP) | VAF 30/73 reads (41%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs786202962, COSV52660760, COSV52661329, COSV52678029; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ADCY3 | c.2543T>C p.L848P | Missense Mutation (SNP) | VAF 27/74 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.027); catalogued as COSV53168682; called by muse, mutect2, varscan2
- ADGRE1 | c.1132G>A p.E378K | Missense Mutation (SNP) | VAF 20/394 reads (5%) | SIFT tolerated (0.26); PolyPhen benign (0.007); catalogued as rs759733050, COSV51676845; called by muse, mutect2
- AFF4 | c.2340G>C p.K780N | Missense Mutation (SNP) | VAF 16/276 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV54795886; called by muse, mutect2
- AKR1C4 | c.110T>A p.V37D | Missense Mutation (SNP) | VAF 6/104 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as COSV54123707; called by muse, mutect2
- BSND | c.77T>A p.M26K | Missense Mutation (SNP) | VAF 46/171 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.776); catalogued as COSV64870792; called by muse, mutect2, varscan2
- CACNB2 | c.1171C>T p.P391S (on ENST00000324631 / NM_201596.3; = p.P336S on NM_000724.4) | Missense Mutation (SNP) | VAF 37/170 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV56630545; called by muse, mutect2, varscan2
- CEP63 | c.1696C>T p.H566Y | Missense Mutation (SNP) | VAF 13/260 reads (5%) | SIFT tolerated (0.08); PolyPhen benign (0.346); catalogued as COSV59676991; called by muse, mutect2
- CHST5 | c.527C>T p.T176M | Missense Mutation (SNP) | VAF 65/380 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.717); catalogued as rs769565596, COSV60337156; called by muse, mutect2, varscan2
- CNGA3 | c.1462G>A p.A488T | Missense Mutation (SNP) | VAF 10/72 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.231); catalogued as rs1013072215, COSV55625137; called by muse, mutect2
- COL4A4 | c.298C>T p.P100S | Missense Mutation (SNP) | VAF 17/125 reads (14%) | SIFT tolerated (0.55); PolyPhen possibly damaging (0.703); catalogued as COSV61633193; called by muse, mutect2, varscan2
- CYC1 | c.239C>A p.S80* | Nonsense Mutation (SNP) | VAF 32/136 reads (24%) | catalogued as COSV59644538; called by muse, mutect2, varscan2
- GPAM | c.895-1G>T p.X299_splice | Splice Site (SNP) | VAF 14/49 reads (29%) | catalogued as COSV62081430; called by muse, mutect2, varscan2
- HFM1 | c.1936A>T p.T646S | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated (0.2); PolyPhen benign (0.153); catalogued as COSV54029469; called by muse, mutect2, varscan2
- ICAM3 | c.308C>G p.S103C | Missense Mutation (SNP) | VAF 22/354 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.886); catalogued as COSV50329267; called by muse, mutect2
- IGHG2 | c.326G>A p.C109Y | Missense Mutation (SNP) | VAF 16/372 reads (4%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.949); catalogued as rs746305578; called by muse, mutect2
- ITGA10 | c.2660G>C p.G887A | Missense Mutation (SNP) | VAF 21/159 reads (13%) | SIFT tolerated (0.42); PolyPhen benign (0.217); catalogued as COSV65197791; called by muse, mutect2, varscan2
- KCNJ11 | c.418G>A p.E140K | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV60594908; called by muse, mutect2, varscan2
- LDHD | c.76G>C p.E26Q | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as COSV55581173; called by muse, mutect2, varscan2
- LGALS12 | c.558+1G>C p.X186_splice | Splice Site (SNP) | VAF 9/98 reads (9%) | catalogued as COSV55370645; called by muse, mutect2, varscan2
- MAPK8IP1 | c.917G>T p.R306L | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV53796895, COSV53798019; called by muse, mutect2, varscan2
- MEN1 | c.1237G>C p.E413Q | Missense Mutation (SNP) | VAF 19/137 reads (14%) | SIFT tolerated (0.05); PolyPhen benign (0.148); catalogued as CD982773, COSV53644602; called by muse, mutect2, varscan2
- MLPH | c.1021-2A>C p.X341_splice | Splice Site (SNP) | VAF 46/176 reads (26%) | catalogued as COSV52821287; called by muse, mutect2
- NFE2L3 | c.1730C>T p.S577L | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.954); catalogued as COSV50230253; called by muse, mutect2, varscan2
- NPAT | c.2344A>G p.K782E | Missense Mutation (SNP) | VAF 27/83 reads (33%) | SIFT tolerated (0.05); PolyPhen benign (0.359); catalogued as COSV53718755; called by muse, mutect2, varscan2
- OR11L1 | c.613G>T p.A205S | Missense Mutation (SNP) | VAF 96/227 reads (42%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.544); catalogued as COSV63314787; called by muse, mutect2, varscan2
- OR4K1 | c.124A>T p.N42Y | Missense Mutation (SNP) | VAF 88/262 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53460608; called by muse, mutect2, varscan2
- OR5L1 | c.718A>T p.T240S | Missense Mutation (SNP) | VAF 31/107 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61734261, COSV61735578; called by muse, mutect2, varscan2
- PAK5 | c.1052C>T p.P351L | Missense Mutation (SNP) | VAF 83/291 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.015); catalogued as rs774991929, COSV62029838, COSV62031425; called by muse, mutect2, varscan2
- PEG3 | c.781G>A p.A261T | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV55636797; called by muse, mutect2
- PIK3R1 | c.339G>C p.L113F | Missense Mutation (SNP) | VAF 14/274 reads (5%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as COSV57131882; called by muse, mutect2
- PTPRK | c.821C>G p.S274* | Nonsense Mutation (SNP) | VAF 36/85 reads (42%) | catalogued as COSV63887895; called by muse, mutect2, varscan2
- PTTG1 | c.436C>T p.L146F | Missense Mutation (SNP) | VAF 5/89 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61678061; called by muse, mutect2
- RB1 | c.219_220dup p.A74Efs*4 | Frame Shift Ins (INS) | VAF 31/85 reads (36%) | catalogued as COSV57297594; called by mutect2, varscan2
- RETREG2 | c.1324C>G p.L442V | Missense Mutation (SNP) | VAF 120/348 reads (34%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs761297856, COSV56087850; called by muse, mutect2, varscan2
- RPS6KB2 | c.1093C>T p.Q365* | Nonsense Mutation (SNP) | VAF 42/135 reads (31%) | catalogued as COSV57051165; called by muse, mutect2, varscan2
- SEMA7A | c.1747G>A p.V583M | Missense Mutation (SNP) | VAF 69/240 reads (29%) | SIFT tolerated (0.1); PolyPhen benign (0.407); catalogued as rs183138976, COSV56090881; called by muse, mutect2, varscan2
- SERPINF2 | c.526G>C p.E176Q | Missense Mutation (SNP) | VAF 17/36 reads (47%) | SIFT tolerated (0.3); PolyPhen benign (0.047); catalogued as COSV60664687; called by muse, mutect2, varscan2
- SLC12A6 | c.694A>G p.M232V (on ENST00000354181 / NM_001365088.1; = p.M181V on NM_005135.2) | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.043); catalogued as rs746413340, COSV51627069; called by muse, mutect2, varscan2
- SLC34A3 | c.1382G>T p.W461L | Missense Mutation (SNP) | VAF 12/141 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV63187346; called by muse, mutect2
- SMPD3 | c.1408G>T p.A470S | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT tolerated (0.59); PolyPhen benign (0.015); catalogued as COSV54712090, COSV54713184; called by muse, mutect2, varscan2
- TMEM94 | c.3098C>T p.T1033I | Missense Mutation (SNP) | VAF 27/195 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.212); catalogued as rs1466855403, COSV58596850; called by muse, mutect2, varscan2
- TNPO1 | c.1292C>T p.A431V | Missense Mutation (SNP) | VAF 28/72 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); catalogued as COSV61522234; called by muse, mutect2, varscan2
- TSPOAP1 | c.4234C>G p.P1412A | Missense Mutation (SNP) | VAF 28/176 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.197); catalogued as rs752915043, COSV52105653, COSV52110656; called by muse, mutect2, varscan2
- UTP25 | c.995G>T p.R332L | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT tolerated (0.81); PolyPhen benign (0.007); catalogued as COSV71965891, COSV71965996; called by muse, mutect2, varscan2
- ZNF337 | c.1347A>T p.K449N | Missense Mutation (SNP) | VAF 9/215 reads (4%) | SIFT tolerated (0.53); PolyPhen benign (0.007); catalogued as COSV53321809; called by muse, mutect2
- ZNF718 | c.650A>G p.H217R | Missense Mutation (SNP) | VAF 11/15 reads (73%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as rs781888099, COSV68140464; called by muse, mutect2, varscan2
- AP1M2 | c.692_694del p.V231del | In Frame Del (DEL) | VAF 26/255 reads (10%) | called by mutect2, pindel, varscan2
- PRAMEF15 | c.1042G>T p.E348* | Nonsense Mutation (SNP) | VAF 30/660 reads (5%) | called by muse, mutect2
- ERC1 | c.1080G>A p.L360= | Silent (SNP) | VAF 8/146 reads (5%) | catalogued as COSV61696097; called by muse, mutect2
- FCRL2 | c.768G>C p.L256= | Silent (SNP) | VAF 162/406 reads (40%) | catalogued as COSV63833892; called by muse, mutect2, varscan2
- MAGT1 | c.75C>G p.P25= (on ENST00000618282 / NM_001367916.1; = p.P57= on NM_032121.5) | Silent (SNP) | VAF 20/38 reads (53%) | catalogued as COSV63782039; called by muse, mutect2, varscan2
- MSH3 | c.2385C>G p.L795= | Silent (SNP) | VAF 9/85 reads (11%) | catalogued as COSV54154069; called by muse, mutect2, varscan2
- MUC16 | c.37524G>A p.R12508= | Silent (SNP) | VAF 447/505 reads (89%) | catalogued as COSV67473139; called by muse, mutect2, varscan2
- SLITRK1 | c.1455C>T p.S485= | Silent (SNP) | VAF 27/82 reads (33%) | catalogued as COSV65676383; called by muse, mutect2, varscan2
- TENM1 | c.1899T>C p.C633= | Silent (SNP) | VAF 130/221 reads (59%) | catalogued as COSV64434456; called by muse, mutect2, varscan2
- ZW10 | c.1938G>A p.V646= | Silent (SNP) | VAF 17/128 reads (13%) | catalogued as COSV52317110, COSV52320062; called by muse, mutect2, varscan2
- BIRC8 | n.1113G>C | RNA (SNP) | VAF 47/137 reads (34%) | catalogued as rs1413137247, COSV70347258; called by muse, mutect2, varscan2
